Somatic mutation profile of tumor specimen TCGA-DD-AADV-01A (aliquot TCGA-DD-AADV-01A-11D-A38X-10) from TCGA case TCGA-DD-AADV, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 50.1 years (18,300 days).
Specimen TCGA-DD-AADV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5bcdb1ea-8b98-4305-9074-02363c36cdfe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AADV-10A (Blood Derived Normal), aliquot TCGA-DD-AADV-10A-01D-A38X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cae8553b-a823-43a1-a8de-8d03449716a9

The open-access MAF lists 110 somatic variants for this specimen: 86 protein-altering or splice-affecting, 23 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 23, Nonsense Mutation 3, Frame Shift Del 2, Nonstop Mutation 1, Frame Shift Ins 1, 5'UTR 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC3 | c.2120A>G p.E707G | Missense Mutation (SNP) | VAF 6/109 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.413); catalogued as rs1283576523, COSV99558718; called by muse, mutect2
- ACIN1 | c.2971A>G p.I991V | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.094); catalogued as COSV99399098; called by muse, mutect2, varscan2
- ADCY8 | c.2749C>T p.Q917* | Nonsense Mutation (SNP) | VAF 47/95 reads (49%) | catalogued as COSV99650858; called by muse, mutect2, varscan2
- AKAP17A | c.1780G>C p.G594R | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated, low confidence (0.95); PolyPhen possibly damaging (0.644); catalogued as rs199895489, COSV100001811, COSV100001910; called by muse, mutect2, varscan2
- ARRDC3 | c.922G>A p.V308I | Missense Mutation (SNP) | VAF 73/250 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99475168; called by muse, mutect2, varscan2
- ATP11C | c.2679G>C p.L893F | Missense Mutation (SNP) | VAF 20/418 reads (5%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.964); catalogued as COSV100557455; called by muse, mutect2
- ATXN7L3 | c.69A>G p.I23M | Missense Mutation (SNP) | VAF 55/147 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs1463318257, COSV101231727; called by muse, mutect2, varscan2
- BUD13 | c.859A>G p.S287G | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV99496249; called by muse, mutect2, varscan2
- C1GALT1 | c.458A>G p.Y153C | Missense Mutation (SNP) | VAF 94/215 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); catalogued as COSV99777504; called by muse, mutect2, varscan2
- CALHM1 | c.685A>T p.K229* | Nonsense Mutation (SNP) | VAF 34/88 reads (39%) | catalogued as COSV99588263; called by muse, mutect2, varscan2
- CD44 | c.1768A>G p.T590A | Missense Mutation (SNP) | VAF 41/165 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV99555441; called by muse, mutect2, varscan2
- CD80 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.643); catalogued as COSV99958153; called by muse, mutect2
- CLCA2 | c.1043T>A p.F348Y | Missense Mutation (SNP) | VAF 6/117 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV100991371; called by muse, mutect2
- CLEC18B | c.1307G>A p.R436Q | Missense Mutation (SNP) | VAF 23/250 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.297); catalogued as rs745534108, COSV100375722; called by muse, mutect2
- CNTNAP2 | c.218G>A p.G73E | Missense Mutation (SNP) | VAF 50/97 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100663014, COSV100664094; called by muse, mutect2, varscan2
- CUBN | c.1205A>T p.H402L | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV100912098; called by muse, mutect2, varscan2
- DDX3Y | c.1769G>C p.R590T | Missense Mutation (SNP) | VAF 71/120 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as COSV100267474; called by muse, mutect2, varscan2
- DLG5 | c.3146G>T p.S1049I | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100967272; called by muse, mutect2, varscan2
- DMGDH | c.2156G>A p.R719H | Missense Mutation (SNP) | VAF 10/269 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1189207901, COSV54866045; called by muse, mutect2
- DNAI2 | c.559T>A p.F187I | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100209591; called by muse, mutect2, varscan2
- ERICH3 | c.242A>C p.E81A | Missense Mutation (SNP) | VAF 173/393 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100443479; called by muse, mutect2, varscan2
- ETS1 | c.1296G>C p.M432I | Missense Mutation (SNP) | VAF 62/130 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV100090087; called by muse, mutect2, varscan2
- FAM117A | c.584C>G p.P195R | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.962); catalogued as rs780032318, COSV99544484; called by muse, varscan2
- FANCD2 | c.152T>G p.L51R | Missense Mutation (SNP) | VAF 16/260 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99810428; called by muse, mutect2
- FANCF | c.649C>T p.R217W | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as rs940463318, COSV100541764; called by muse, mutect2, varscan2
- FBXO42 | c.1618C>G p.P540A | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100981651, COSV100981685; called by muse, mutect2, varscan2
- FSCB | c.2014C>A p.P672T | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.031); catalogued as COSV100468887; called by muse, mutect2, varscan2
- H2AC11 | c.5C>G p.S2C | Missense Mutation (SNP) | VAF 72/110 reads (65%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.091); catalogued as COSV100345610, COSV60361677; called by muse, mutect2, varscan2
- HSPD1 | c.844G>C p.A282P | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV100798249; called by muse, mutect2, varscan2
- INSRR | c.2440G>A p.E814K | Missense Mutation (SNP) | VAF 55/108 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV100947169; called by muse, mutect2, varscan2
- JAK1 | c.988A>T p.N330Y | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100691094; called by muse, mutect2, varscan2
- KIDINS220 | c.4424C>G p.P1475R | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as COSV99874994; called by muse, mutect2
- LAX1 | c.523A>G p.N175D | Missense Mutation (SNP) | VAF 60/172 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.117); catalogued as COSV100919990; called by muse, mutect2
- LHCGR | c.1439T>C p.L480S | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54293936; called by muse, mutect2, varscan2
- LLPH | c.170A>G p.H57R | Missense Mutation (SNP) | VAF 82/280 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV99874457; called by muse, mutect2, varscan2
- LRRC4C | c.664G>T p.D222Y | Missense Mutation (SNP) | VAF 57/136 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV53437898, COSV99538561; called by muse, mutect2, varscan2
- MAST4 | c.854C>G p.S285W (on ENST00000403625 / NM_001164664.2; = p.S96W on NM_015183.3) | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55141559; called by muse, mutect2, varscan2
- MCM7 | c.988G>C p.E330Q | Missense Mutation (SNP) | VAF 52/91 reads (57%) | SIFT tolerated (0.35); PolyPhen benign (0.215); catalogued as COSV100384648; called by muse, mutect2, varscan2
- MEF2A | c.206A>G p.Y69C | Missense Mutation (SNP) | VAF 80/190 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100573557; called by muse, mutect2, varscan2
- MKRN3 | c.1462T>C p.S488P | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.694); catalogued as COSV100090769; called by muse, mutect2
- MMP1 | c.1301G>A p.G434E | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.288); catalogued as COSV59510909; called by muse, mutect2, varscan2
- MPPED1 | c.767C>T p.P256L | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.536); catalogued as COSV68838428; called by muse, mutect2, varscan2
- MSH4 | c.1682C>T p.S561F | Missense Mutation (SNP) | VAF 111/422 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.166); catalogued as rs759216786, COSV99590710; called by muse, mutect2, varscan2
- MYBPC2 | c.2179A>G p.N727D | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as COSV100731606; called by muse, mutect2, varscan2
- MYOT | c.1091A>G p.D364G | Missense Mutation (SNP) | VAF 229/552 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.093); catalogued as COSV99296022; called by muse, mutect2, varscan2
- NF1 | c.5407A>G p.I1803V (on ENST00000358273 / NM_001042492.3; = p.I1782V on NM_000267.3) | Missense Mutation (SNP) | VAF 54/104 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as rs559910904, COSV100646079; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NKX6-2 | c.385G>T p.D129Y | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.898); catalogued as COSV100888322; called by muse, mutect2
- NPEPPS | c.1942A>C p.N648H | Missense Mutation (SNP) | VAF 57/125 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV100443437; called by muse, mutect2, varscan2
- OCM | c.195G>T p.K65N | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.741); catalogued as rs1482427502, COSV99631316; called by muse, mutect2, varscan2
- ORC1 | c.230A>T p.D77V | Missense Mutation (SNP) | VAF 96/215 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.403); catalogued as COSV100856590; called by muse, mutect2, varscan2
- ORMDL1 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100360550; called by muse, mutect2, varscan2
- PCDHA8 | c.1087G>C p.A363P | Missense Mutation (SNP) | VAF 68/290 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV100970462; called by muse, mutect2, varscan2
- PCF11 | c.1159C>A p.Q387K | Missense Mutation (SNP) | VAF 6/149 reads (4%) | SIFT tolerated (0.93); PolyPhen possibly damaging (0.9); catalogued as COSV100017847; called by muse, mutect2
- PDE6A | c.2336T>C p.F779S | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.959); catalogued as COSV99677836; called by muse, mutect2, varscan2
- PDIK1L | c.1026A>G p.*342Wext*24 | Nonstop Mutation (SNP) | VAF 23/81 reads (28%) | catalogued as COSV100957657; called by muse, mutect2, varscan2
- PMFBP1 | c.1000G>A p.V334M | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs144745394; called by muse, mutect2, varscan2
- PPEF2 | c.704A>G p.H235R | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as rs1292742576, COSV99714150; called by muse, mutect2, varscan2
- PPP1R9A | c.2711A>G p.Y904C | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV99194643; called by muse, mutect2, varscan2
- PRKACA | c.470A>G p.Y157C | Missense Mutation (SNP) | VAF 45/167 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100431772; called by muse, mutect2, varscan2
- PTPRN2 | c.205T>A p.F69I | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV101233723, COSV67042711; called by muse, mutect2, varscan2
- RAVER2 | c.1765A>G p.S589G (on ENST00000294428 / NM_001366165.1; = p.S576G on NM_018211.4) | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99604832; called by muse, mutect2, varscan2
- RFX6 | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.864); catalogued as COSV100263307; called by muse, mutect2, varscan2
- RNF126 | c.397A>T p.T133S | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as COSV99442906; called by muse, mutect2, varscan2
- SCAF11 | c.2492A>C p.Q831P | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.361); catalogued as COSV101014093; called by muse, mutect2
- SDHAF2 | c.96A>C p.R32S | Missense Mutation (SNP) | VAF 53/108 reads (49%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV100073881; called by muse, mutect2, varscan2
- SF3B1 | c.2132C>T p.A711V | Missense Mutation (SNP) | VAF 138/308 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100133877, COSV59227447; called by muse, mutect2, varscan2
- SHB | c.772A>C p.S258R | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.034); catalogued as COSV100891045; called by muse, mutect2
- SLAMF7 | c.781G>C p.E261Q | Missense Mutation (SNP) | VAF 6/144 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.109); catalogued as COSV100833205; called by muse, mutect2
- SLC20A1 | c.419T>G p.F140C | Missense Mutation (SNP) | VAF 69/190 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99733884; called by muse, mutect2, varscan2
- SNAP91 | c.2569G>A p.V857I | Missense Mutation (SNP) | VAF 89/163 reads (55%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.891); catalogued as COSV99534492; called by muse, mutect2, varscan2
- STAB1 | c.5047C>T p.L1683F | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as rs1559715152, COSV100401253; called by muse, mutect2
- SYDE2 | c.3134A>T p.Q1045L | Missense Mutation (SNP) | VAF 52/113 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.225); catalogued as COSV100415613; called by muse, mutect2, varscan2
- TINAG | c.1247C>T p.T416I | Missense Mutation (SNP) | VAF 184/363 reads (51%) | SIFT tolerated (0.69); PolyPhen benign (0.089); catalogued as COSV99448678; called by muse, mutect2, varscan2
- TOE1 | c.737A>G p.Y246C | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100517084; called by muse, mutect2, varscan2
- TOMM70 | c.1625A>G p.N542S | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.044); catalogued as rs756746228, COSV99424133; called by muse, mutect2, varscan2
- TP53 | c.318C>G p.S106R | Missense Mutation (SNP) | VAF 76/103 reads (74%) | SIFT tolerated (0.41); PolyPhen benign (0.149); catalogued as rs1555526581, CM013441, COSV52748282, COSV52919256, COSV53146850; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRMT5 | c.154G>A p.G52S | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); catalogued as COSV99711928; called by muse, mutect2, varscan2
- TTLL4 | c.2593A>G p.I865V | Missense Mutation (SNP) | VAF 67/138 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.262); catalogued as rs201011157, COSV104383975; called by muse, mutect2, varscan2
- TUBB8 | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 67/159 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.616); catalogued as COSV100225931; called by muse, mutect2, varscan2
- WDR90 | c.4012G>T p.E1338* | Nonsense Mutation (SNP) | VAF 15/38 reads (39%) | catalogued as COSV99552758; called by muse, mutect2, varscan2
- XIRP2 | c.378G>T p.Q126H (on ENST00000628543; = p.Q301H on NM_152381.6) | Missense Mutation (SNP) | VAF 23/388 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); catalogued as COSV99738822; called by muse, mutect2
- XRN2 | c.1822A>T p.N608Y | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as COSV101018021; called by muse, mutect2, varscan2
- FANCF | c.162del p.R55Afs*26 | Frame Shift Del (DEL) | VAF 36/150 reads (24%) | called by mutect2, pindel, varscan2
- RASGRF2 | c.3544del p.M1182* | Frame Shift Del (DEL) | VAF 20/82 reads (24%) | called by pindel, varscan2
- RASGRF2 | c.3550A>C p.M1184L | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.118); called by muse, varscan2
- TMEM128 | c.154dup p.S52Ffs*16 (on ENST00000382753 / NM_001297552.2; = p.S28Ffs*16 on NM_032927.3) | Frame Shift Ins (INS) | VAF 43/134 reads (32%) | called by mutect2, pindel, varscan2
- ADAM18 | c.1914T>C p.N638= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as COSV99694938; called by muse, mutect2, varscan2
- ARMCX3 | c.330C>T p.S110= | Silent (SNP) | VAF 39/77 reads (51%) | catalogued as COSV100362187; called by muse, mutect2, varscan2
- CEP152 | c.4128T>C p.V1376= (on ENST00000380950 / NM_001194998.2; = p.V1320= on NM_014985.4) | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as COSV100358537; called by muse, mutect2, varscan2
- CSN1S1 | c.255C>A p.S85= | Silent (SNP) | VAF 30/136 reads (22%) | catalogued as COSV99886540; called by muse, mutect2, varscan2
- DRC1 | c.1272C>T p.H424= | Silent (SNP) | VAF 20/87 reads (23%) | catalogued as COSV99985044; called by muse, mutect2, varscan2
- DSP | c.6315A>G p.V2105= | Silent (SNP) | VAF 9/138 reads (7%) | catalogued as rs1169852065, COSV101131186; called by muse, mutect2
- ERN2 | c.1008A>G p.R336= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV99890611; called by muse, mutect2, varscan2
- F2RL1 | c.648C>T p.I216= | Silent (SNP) | VAF 41/101 reads (41%) | catalogued as COSV99688659; called by muse, mutect2, varscan2
- IQSEC3 | c.1959G>T p.R653= (on ENST00000538872 / NM_001170738.2; = p.R350= on NM_015232.1) | Silent (SNP) | VAF 67/164 reads (41%) | catalogued as COSV100406858; called by muse, mutect2, varscan2
- KIF17 | c.606G>C p.L202= | Silent (SNP) | VAF 8/146 reads (5%) | catalogued as COSV99928570; called by muse, mutect2
- LRFN1 | c.834C>T p.P278= | Silent (SNP) | VAF 40/82 reads (49%) | catalogued as rs774384259, COSV99952655; called by muse, mutect2, varscan2
- MAP11 | c.420G>T p.V140= | Silent (SNP) | VAF 56/116 reads (48%) | catalogued as COSV100385359; called by muse, mutect2, varscan2
- MIER3 | c.753A>G p.L251= | Silent (SNP) | VAF 31/63 reads (49%) | catalogued as rs1194620159, COSV100423515; called by muse, mutect2, varscan2
- MUC16 | c.29949C>T p.T9983= | Silent (SNP) | VAF 65/161 reads (40%) | catalogued as COSV101198313, COSV67462245; called by muse, mutect2, varscan2
- MUC5B | c.12550C>T p.L4184= | Silent (SNP) | VAF 30/474 reads (6%) | catalogued as rs774559269, COSV101500049, COSV71594693; called by muse, mutect2
- PAM | c.2052T>A p.T684= | Silent (SNP) | VAF 5/103 reads (5%) | catalogued as COSV99173077; called by muse, mutect2
- PDXDC1 | c.1437A>T p.V479= | Silent (SNP) | VAF 15/119 reads (13%) | catalogued as COSV100362900; called by muse, mutect2
- RCC2 | c.987C>T p.N329= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as COSV64905261; called by muse, mutect2, varscan2
- SDK1 | c.3519C>G p.P1173= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV101268794, COSV101268808; called by muse, mutect2, varscan2
- SMC4 | c.2823C>G p.V941= | Silent (SNP) | VAF 102/264 reads (39%) | catalogued as COSV100557428; called by muse, mutect2, varscan2
- SPOCK3 | c.1095T>C p.Y365= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs1370164087, COSV100691986; called by muse, mutect2, varscan2
- SYN1 | c.39T>C p.F13= | Silent (SNP) | VAF 78/683 reads (11%) | catalogued as COSV55949650, COSV99901308; called by muse, mutect2, varscan2
- ZFC3H1 | c.5847A>G p.E1949= | Silent (SNP) | VAF 19/84 reads (23%) | catalogued as COSV101110347; called by muse, mutect2, varscan2
- CLU | c.-34G>A | 5'UTR (SNP) | VAF 70/129 reads (54%) | catalogued as COSV57068245; called by muse, mutect2, varscan2
